Somatic mutation profile of tumor specimen TCGA-77-8138-01A (aliquot TCGA-77-8138-01A-11D-2244-08) from TCGA case TCGA-77-8138, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,225 days).
Specimen TCGA-77-8138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89f1800d-7ee8-4f2c-b0e3-be58406d3857.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8138-10A (Blood Derived Normal), aliquot TCGA-77-8138-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b5f8018-af3f-46db-9a96-c4dda0d1516c

The open-access MAF lists 105 somatic variants for this specimen: 81 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 23, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 3, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASDH | c.1458G>T p.M486I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99220751; called by muse, mutect2, varscan2
- ADAMTS12 | c.2144-1G>C p.X715_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100710241, COSV61283954; called by muse, mutect2, varscan2
- ADGRE2 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100215662; called by muse, mutect2, varscan2
- ANKRD30A | c.2666del p.S889Lfs*9 (on ENST00000611781; = p.S833Lfs*9 on NM_052997.2) | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as COSV100653521, COSV64609685; called by mutect2, varscan2
- APBA1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99595361; called by muse, mutect2, varscan2
- APBB1 | c.670T>G p.W224G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100193529; called by muse, mutect2
- BMP5 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100895734; called by muse, mutect2, varscan2
- BMP5 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.011); catalogued as COSV100895735; called by muse, mutect2, varscan2
- CARD11 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs752709289, COSV62754385, COSV62754470, COSV62755617; called by muse, mutect2
- CATSPERB | c.2302G>C p.G768R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99830772, COSV99830889; called by muse, mutect2, varscan2
- CCDC88B | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100104968; called by muse, mutect2
- CDH10 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV52576463; called by muse, mutect2, varscan2
- CLSTN3 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866480; called by muse, mutect2, varscan2
- COL11A1 | c.5377C>G p.Q1793E | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1409700354, COSV100614951; called by muse, mutect2, varscan2
- COL11A1 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV100614954, COSV100615907; called by muse, mutect2, varscan2
- COL22A1 | c.2653C>A p.Q885K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.287); catalogued as COSV100276184; called by muse, mutect2, varscan2
- CPN1 | c.599T>A p.V200E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100962542; called by muse, mutect2, varscan2
- CTTNBP2 | c.1287T>A p.H429Q | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99352939; called by muse, mutect2, varscan2
- DPP10 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100058217; called by muse, mutect2, varscan2
- ENPP2 | c.1077C>G p.D359E (on ENST00000075322 / NM_001040092.3; = p.D411E on NM_006209.5) | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99307432; called by muse, mutect2
- ESR2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs764756707, COSV99962787; called by muse, mutect2, varscan2
- EVI5 | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV100945025; called by muse, mutect2, varscan2
- FAM83H | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101186918; called by muse, mutect2, varscan2
- FHIT | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100532788; called by muse, mutect2, varscan2
- FYB1 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV60959467; called by muse, mutect2, varscan2
- GAL | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99681833; called by muse, mutect2, varscan2
- GINM1 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs564649407, COSV100805278; called by muse, mutect2, varscan2
- GRID2 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56207248, COSV99936986; called by muse, mutect2
- GRIN2B | c.4297G>A p.A1433T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV101662903; called by muse, mutect2, varscan2
- GRIN2B | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.22); catalogued as COSV101662904; called by muse, mutect2, varscan2
- HECTD1 | c.5876C>G p.T1959R | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV67949734; called by muse, mutect2, varscan2
- HLA-DPB1 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV101330960; called by muse, mutect2, varscan2
- IGHV4-39 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs753404788; called by muse, mutect2, varscan2
- IL1R1 | c.1660C>G p.P554A | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99292346, COSV99292506; called by muse, mutect2, varscan2
- JHY | c.1514T>C p.L505P | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99912688; called by muse, mutect2, varscan2
- KLHL10 | c.1362C>A p.N454K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV99509411; called by muse, mutect2, varscan2
- KRTAP5-1 | c.393T>A p.C131* | Nonsense Mutation (SNP) | VAF 34/254 reads (13%) | catalogued as rs1233821596, COSV101192864; called by muse, varscan2
- KTN1 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101254958; called by muse, mutect2, varscan2
- MED12L | c.1852A>T p.M618L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99851420; called by muse, mutect2, varscan2
- MEGF10 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs754251946, COSV57250761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MKI67 | c.4310C>T p.T1437I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100896142; called by muse, mutect2, varscan2
- MMS22L | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV99246027; called by muse, mutect2
- MTARC1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs779576139, COSV100856237; called by muse, mutect2, varscan2
- NAA16 | c.2010T>G p.D670E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101049719; called by muse, mutect2, varscan2
- NAV3 | c.6658A>G p.T2220A (on ENST00000397909 / NM_001024383.2; = p.T2198A on NM_014903.6) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99886698; called by muse, mutect2, varscan2
- OPA3 | c.144G>A p.L48= | Splice Region (SNP) | VAF 17/238 reads (7%) | catalogued as COSV99840818; called by muse, mutect2
- OR14K1 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99314952; called by muse, mutect2, varscan2
- OR2M4 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV100140964, COSV60707561; called by muse, mutect2
- OR4K15 | c.479T>C p.M160T (on ENST00000305051; = p.M136T on NM_001005486.1) | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100520962; called by muse, mutect2, varscan2
- OR51E2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.086); catalogued as COSV101211306; called by muse, varscan2
- OR51S1 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100437336; called by muse, varscan2
- OR5A2 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100119663; called by muse, mutect2, varscan2
- PDGFRA | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV99955380; called by muse, mutect2, varscan2
- PGBD5 | c.365G>T p.G122V (on ENST00000525115; = p.G191V on NM_001258311.2) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100358350, COSV58410348; called by muse, mutect2, varscan2
- PGBD5 | c.364G>C p.G122R (on ENST00000525115; = p.G191R on NM_001258311.2) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100358351, COSV58414260; called by muse, mutect2, varscan2
- PLEKHG7 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV60823085; called by muse, mutect2, varscan2
- PXDN | c.2828G>T p.R943L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.421); catalogued as COSV53227068, COSV99412218; called by muse, mutect2, varscan2
- RANBP2 | c.9520A>G p.I3174V | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV51709474; called by muse, mutect2, varscan2
- RASA1 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99169595, COSV99169597; called by muse, mutect2, varscan2
- RELL1 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100025238; called by muse, mutect2
- SEMA7A | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as rs760934713, COSV99984534; called by muse, mutect2, varscan2
- SLC13A1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99520368; called by muse, varscan2
- SLITRK5 | c.140T>A p.I47N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1312850494, COSV100280235; called by muse, mutect2
- SUCO | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV99741950; called by muse, mutect2, varscan2
- TEX44 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100009572; called by muse, mutect2
- TGIF2LX | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99383162; called by muse, mutect2, varscan2
- TLE4 | c.252+2T>G p.X84_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99511082; called by muse, mutect2, varscan2
- TRAK2 | c.2068A>G p.S690G | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100216599; called by muse, mutect2, varscan2
- TTN | c.6792T>A p.G2264= (on ENST00000591111; = p.G2218= on NM_003319.4) | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100593173; called by muse, mutect2, varscan2
- TULP4 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100893079; called by muse, mutect2, varscan2
- USP13 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV99830702; called by muse, mutect2, varscan2
- VPS13C | c.11161-2A>G p.X3721_splice (on ENST00000644861 / NM_020821.3; = p.X3678_splice on NM_017684.5) | Splice Site (SNP) | VAF 16/124 reads (13%) | catalogued as COSV99826940; called by muse, mutect2, varscan2
- VPS13C | c.8608C>T p.P2870S (on ENST00000644861 / NM_020821.3; = p.P2827S on NM_017684.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51124263; called by muse, mutect2, varscan2
- YES1 | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV100099168; called by muse, mutect2
- ZIC1 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as rs765916669, COSV51553989; called by muse, mutect2, varscan2
- ZNF347 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 32/142 reads (23%) | catalogued as COSV100498109; called by muse, mutect2, varscan2
- MYOC | c.316del p.Q106Rfs*19 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- NF1 | c.3749_3759del p.R1250Lfs*10 | Frame Shift Del (DEL) | VAF 42/286 reads (15%) | called by mutect2, pindel
- RDX | c.1377del p.E461Kfs*3 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel, varscan2
- ZFPM1 | c.2567G>A p.C856Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- ABCC1 | c.2037G>A p.Q679= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100578460; called by muse, mutect2, varscan2
- ADCY2 | c.3078T>C p.N1026= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100601703; called by muse, mutect2, varscan2
- ANKLE2 | c.792C>T p.S264= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100513911; called by muse, mutect2, varscan2
- CDH10 | c.2253A>G p.L751= | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as COSV100049943, COSV52574857; called by muse, mutect2, varscan2
- CFAP61 | c.2223G>T p.V741= | Silent (SNP) | VAF 14/243 reads (6%) | catalogued as COSV99843132; called by muse, mutect2
- CHST15 | c.48A>C p.A16= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs1316672459, COSV100654921; called by muse, mutect2, varscan2
- DGCR8 | c.27G>A p.P9= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1179438081, COSV100707797; called by muse, mutect2
- GREB1 | c.3159C>A p.S1053= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99302171; called by muse, mutect2, varscan2
- GRM5 | c.627C>T p.Y209= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100550060; called by muse, mutect2, varscan2
- HSPBP1 | c.580C>A p.R194= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs374807828, COSV99728915; called by muse, varscan2
- IFNA7 | c.429G>C p.V143= | Silent (SNP) | VAF 55/287 reads (19%) | catalogued as COSV99497354; called by muse, mutect2, varscan2
- IGKV1-9 | c.273A>G p.T91= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs1298706612; called by muse, mutect2
- IMPA2 | c.396G>T p.V132= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99302373; called by muse, mutect2, varscan2
- NEUROD6 | c.468A>G p.P156= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV51771935; called by muse, mutect2
- OR2L13 | c.282G>T p.L94= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as COSV100813656; called by muse, mutect2, varscan2
- PACS2 | c.267G>A p.E89= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV100330589; called by muse, mutect2
- PRLR | c.177T>C p.N59= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99184200; called by muse, mutect2, varscan2
- SLC22A23 | c.1911G>A p.T637= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs771053683, COSV100978102; called by muse, mutect2, varscan2
- ST6GAL2 | c.978T>A p.A326= | Silent (SNP) | VAF 8/159 reads (5%) | catalogued as COSV100699509; called by muse, mutect2
- SYNCRIP | c.210A>G p.E70= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100783984; called by muse, mutect2, varscan2
- TECRL | c.456A>T p.T152= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101168401; called by muse, mutect2, varscan2
- TTN | c.20550A>G p.K6850= (on ENST00000591111; = p.K5923= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1168845666, COSV100593171; called by muse, mutect2
- USP9Y | c.306T>G p.A102= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100168182; called by muse, mutect2, varscan2
- DTNBP1 | c.811+62G>T | Intron (SNP) | VAF 75/310 reads (24%) | catalogued as COSV100160327, COSV100160738; called by muse, mutect2, varscan2
